Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A92D, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A92D-01A (Primary Tumor).

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Cardia)

Product of: 1-Stomach + distal esophagus:

- Moderately differentiated tubule-vilous adenocarcinoma from cardia, focally invasive to subserosa adipose tissue and extensive to distal esophagus.
- Tumor largest size: 6.5 cm.
- Angiolymphatic invasion: not observed.
- Perineural invasion: present.
- Surgical margins: uninvolved by neoplasia.
- Lymph nodes: 21 lymph nodes from lesser curvature and 7 lymph nodes from greater curvature uninvolved by neoplasia (0/28).

2- Esophageal margin:

- Uninvolved by neoplasia."

ICD-O-3

Adenocarcinoma, tubular 8211/3

Site Cardia NOS C16.0

Q12 3/13/14

Source: NCI Genomic Data Commons file 6d3d73ee-4f35-46ad-abc4-4c958d5df66d (TCGA-VQ-A92D.BF14A024-4E24-4C1E-A18D-387D0A55E02D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).